Surgical pathology report (de-identified scan), TCGA case TCGA-XU-A92W, project TCGA-THYM (Thymoma), tissue source site University Health Network, specimen TCGA-XU-A92W-01A (Primary Tumor).

[page 1 of 3]
ICD-O-3
Thymoma, Type AB,
malignant 8582/3
Site: Thymus C37.9
9/4/14

Patient Name:

MRN:

DOB:

Gender:M

Ordering MD:

Service:

Visit #:

Location:

Facility:

Collected:

Resulted:

Surgical Pathology Consultation Report

SPECIMEN(S) RECEIVED

1. Thymus thymoma, partial pericardial resection and partial wedge -RUL
2. Right antro- lateral aspect tumour of aorta

DIAGNOSIS

1. Thymus, resection (thymectomy, partial pericardial resection, partial right upper lobe wedge resection)
- a) Thymoma, WHO type AB2 (mixed thymoma), with:
- i) Greatest dimension = 6.0 cm
- ii) Microscopic invasion of mediastinal fat
- iii) Invasion of pleura, pericardium or lung not identified
- b) Thymic tissue with involutional changes
2. Soft tissue, resection ("right antro-lateral tumour of aorta")
- Benign cyst

SYNOPTIC DATA

Specimen Type:	Not specified
Specimen Size:	Greatest dimension: 21.2 cm
Tumor Site:	Thymus
Tumor Size:	Greatest dimension: 6.0 cm
Histologic Type:	Type AB thymoma (mixed)
Pathologic Staging:	Stage IIa: Microscopic transcapsular invasion
Regional Lymph Nodes:	pNX: Cannot be assessed
Distant Metastasis:	Cannot be assessed
Margins:	Margins uninvolved by tumor
Invasion of Pulmonary Parenchyma:	Absent
Pleural Invasion:	Absent
Vascular (Small/Large Vessel) Invasion:	Absent

Status: complete

Page: 1 of 3

[page 2 of 3]
Department of Pathology

Patient Name:

MRN:

DOB:

Gender:M

Service:

Visit #:

Location:

Facility:

: Collected:

Resulted:

Ordering MD:

COMMENT

1. Sections show a partially encapsulated tumor with lobules separated by thick fibrous septa. Some of the lobules are composed of spindled to oval-shaped cells with bland nuclei and dispersed chromatin, with few lymphocytes. Other areas are composed of roughly equal amounts of cortical-type epithelial cells and small lymphocytes. Focally, the tumor shows microscopic invasion of its capsule and surrounding fat. There is no invasion of the pleura, pericardium or lung. By immunohistochemistry, the epithelial cells stain positive for keratin (AE1/AE3, CK5/6) and focally positive for p63. The small lymphocytes stain positive for CD1a. The overall features are of a WHO type AB2 thymoma, modified Masaoka stage II (minimally invasive).

ELECTRONICALLY VERIFIED BY:

CLINICAL HISTORY

Thymoma

GROSS DESCRIPTION

1. The specimen container labeled with the patient's name and as "thymus, thymoma, partial pericardial resection and partial wedge right upper lobe", contains a piece of unoriented thymus received in 10% buffered formalin. The specimen measures 21.2 x 7.5 x 3.5 cm. The specimen margins are painted with silver nitrate. On gross examination, there is a well-circumscribed tumor on the center of the thymus. The tumor measures 6.0 x 5.5 x 3.5 cm. It is tan in color and appears encapsulated. On sectioning, the cut surface of the tumor is yellowish-tan in color and has whorled appearance. Adherent to one side of the tumor is a wedge of lung measuring 4.5 x 1.5 x 0.9 cm. The lung parenchyma appears grossly unremarkable. Opposite to the lung parenchyma a piece of pericardium is also adherent to one side of the tumor. This pericardial measures 5.5 x 1.5 x 0.2 cm. The pericardium appears to be loosely attached to the tumor. The rest of the residual thymus is yellow-tan in color and appears to be grossly unremarkable. No other nodules are identified grossly. Also in the container is a piece of an unoriented fibroadipose measuring 9.8 x 4.5 x 2.0 cm. On serial

Status: complete

Page: 2 of 3

[page 3 of 3]
Department of Pathology

Patient Name: _____
MRN: _____ Service: _____ Collected: _____
DOB: _____ Visit #: _____ Resulted: _____
Gender: M Location: _____
Facility: _____
Ordering MD: _____

sectioning the cut surface is yellowish-tan in color and predominantly fatty. No nodules are identified grossly. Representative sections are submitted in toto as follows:
1A-1B - pericardial shave resection margin taken en face and submitted in toto
1C-1E - the tumor in relation to the adjacent lung parenchyma
1F-1H- the tumor in relation to the adjacent pericardium
1I- the tumor in relation to the adjacent residual thymus
1J-1K - representative sections of the residual thymus
1L - representative section from the smaller piece of fibroadipose tissue

2. The specimen container labeled with the patient' s name and as "right antro- lateral aspect tumour of aorta", contains one pieces of yellowish-tan tissue measuring 0.8 x 0.6 x 0.4 cm received in 10% buffered formalin.
2A submitted in toto.

Case is (close)		/

Status: complete

Source: NCI Genomic Data Commons file 5d160da6-749b-414c-aa60-8e282643114e (TCGA-XU-A92W.2709A0EE-FBA3-411A-9E07-83FE0824A862.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).